CCDI case PBBPVG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/17df28e6-0522-4b94-8fcb-cca96022835d

Demographics
Sex at birth: female; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Mixed germ cell tumor: ICD-O-3 morphology code: 9085/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.7 years (5,382 days).

Biospecimens (3 samples)
- Sample 0DENBX: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DENCE, 0DENCV (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
